Surgical pathology report (de-identified scan), TCGA case TCGA-HT-7881, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-7881-01A (Primary Tumor).

Pathology Report for Subject [REDACTED]

Addendum Discussion:

A calculated MIB-1 labeling index is 2.7%

Addendum Diagnosis:

Oligodendroglioma, WHO grade II.

Microscopic Description:

Microscopic examination reveals an infiltrating glioma. The tumor is composed of a proliferation of cells with predominantly round nuclei and mild to moderate nuclear pleomorphism. The tumor cells demonstrate prominent perinuclear halos. They diffusely infiltrate the adjacent brain parenchyma. Overall, the tumor appears mildly hypercellular with focal regions showing increased hypercellularity. Occasional cells show more significant cytologic atypia, but overall the atypia appears mild to moderate. Scattered neurons demonstrate perineuronal satellitosis. Up to one mitotic figure per 10 high power field is identified. Neither microvascular proliferation nor necrosis are identified.

Source: NCI Genomic Data Commons file 446471a3-f869-41b6-9380-8878e84476a3 (TCGA-HT-7881.8C9A3353-4D77-4D26-8522-DA3869660C35.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).